Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TS-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Oligodendroglioma
grade II 9450/3
Site: Supratentorial NAS
C71.0
② Brain, frontal lobe
C71.1
MD 4/18/13

Surgical Pathology Report

Patient Name: _____ Phone #: _____ Accession #: _____
Med. Rec. #: _____ Client: _____ Taken: _____
DOB: _____ Location: _____ Received: _____
Gender: M Accnt: _____ Reported: _____
Physician(s): _____
Phy Location: _____

Clinical History

Brain mass

Operative Diagnoses

Operation / Specimen

- A: Brain, right frontal tumor, biopsy
- B: Brain, right frontal tumor, biopsy
- C: Brain, temporal lobe tumor, biopsy

Pathologic Diagnosis

A. – C. Brain, right frontal tumor, biopsies and excision: Oligodendroglioma, WHO grade II (see comment).

Comment

Permanent sections confirm the frozen section diagnosis. Sections show a glioma with mostly oligodendroglial features. Some most angulated cells are also noted suggesting a lesser astrocytic component. Mitotic activity is noted in specimen B. Vascular proliferation and/or necrosis is not seen. The Ki-67 labeling index is up to approximately 8%. Controls show appropriate reactivity. Although the lesion meets criteria for a grade II oligodendroglioma, the focal mitotic activity may suggest that it is in transition to a grade III lesion. Clinical correlation is recommended. Controls show appropriate reactivity.
Electronically Signed Out

Senior Staff Pathologist

Procedures/Addenda

MGMT Promoter Methylation

Date Ordered: _____ Date Reported: _____

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Surgical Pathology

Page 2 of 4

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
H and E slide was examined and no microdissection was needed.
TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into

[page 2 of 3]
unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered:

Date Reported:

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S552, D1S1612, D19S219, D19S412 and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
corresponding blood specimen was used as a normal reference control.

DNA extracted from a

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Surgical Pathology

Page 3 of 4

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[page 3 of 3]
Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, right frontal tumor, biopsy: Glioma, intermediate grade features, some oligodendroglial features.

Request

blood for LOH studies. Frozen section and smears performed at
to the

and results reported

Physician of Record.

Senior Staff Pathologist

Gross Description

A. Brain, right frontal tumor, biopsy:

CONTAINER LABEL: right frontal tumor

FIXATIVE: formalin

GENERAL: after reapproximation, specimen consists of a 1.3 x 0.6 x 0.2 cm aggregate of pink tan soft tissue.

SECTIONS: 2, NS

B. Brain, right frontal tumor, biopsy:

CONTAINER LABEL: R frontal tumor

FIXATIVE: formalin

GENERAL: 2.8 x 2.0 x 1.2 cm aggregate of pink tan focally hemorrhagic soft tissue.

SECTIONS: 2, NS

C. Brain, temporal lobe tumor, biopsy:

CONTAINER LABEL: temporal lobe

FIXATIVE: formalin

GENERAL: 4.4 x 2.8 x 1.7 cm ovoid portion of pink tan soft tissue.

SECTIONS: 5, NS

ICD-9(s): 191.9 191.9

Billing Fee Code(s):

Histo Data

Part A: Brain, right frontal tumor, biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

FS H&E x 1 1

H&E x 1 1

TPS H&E x 1 1

H&E x 1 2

LOH-curly x 1 2

Surgical Pathology

Page 4 of 4

Source: NCI Genomic Data Commons file 35c0a6c6-a7e3-4af7-8039-5e787d3c7a84 (TCGA-DU-A5TS.1D94A4FE-F273-4DD4-AB30-FE47A22542B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).